Somatic mutation profile of cancer-model specimen HCM-WCMC-0786-C34-85A (3D Organoid, passage 9; aliquot HCM-WCMC-0786-C34-85A-01D-A87L-36), derived from the primary tumor of HCMI case HCM-WCMC-0786-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Bronchio-alveolar carcinoma, mucinous; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 76.8 years (28,050 days).
Specimen HCM-WCMC-0786-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e928fd7-ebea-48bc-b970-88b1fc43eb3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0786-C34-10A (Blood Derived Normal), aliquot HCM-WCMC-0786-C34-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8edf6abc-50b1-4054-bd34-09375efe95a8

The open-access MAF lists 80 somatic variants for this specimen: 52 protein-altering or splice-affecting, 23 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 23, Nonsense Mutation 5, Frame Shift Ins 3, Intron 3, Frame Shift Del 2, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD7 | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 42/363 reads (12%) | catalogued as rs587783429, CM060210; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 125/313 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APBB1IP | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV63304235; called by muse, mutect2, varscan2
- C2orf16 | c.4609A>G p.K1537E | Missense Mutation (SNP) | VAF 169/341 reads (50%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.95); catalogued as rs1463877280; called by muse, mutect2, varscan2
- CDC42BPG | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 231/458 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs149057251; called by muse, mutect2, varscan2
- COL6A2 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 13/401 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as rs1473389233; called by muse, mutect2
- DCAF4L2 | c.659C>A p.S220* | Nonsense Mutation (SNP) | VAF 179/393 reads (46%) | catalogued as COSV60478060; called by muse, mutect2, varscan2
- DIO3 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 260/260 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as rs370365050; called by muse, mutect2, varscan2
- DISP3 | c.2257G>A p.A753T | Missense Mutation (SNP) | VAF 243/513 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs199823398, COSV53839940; called by muse, mutect2, varscan2
- EML3 | c.1334C>A p.T445N | Missense Mutation (SNP) | VAF 145/313 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV53904596; called by muse, mutect2, varscan2
- FAM47A | c.1072G>T p.G358* | Nonsense Mutation (SNP) | VAF 275/282 reads (98%) | catalogued as COSV100649780; called by muse, mutect2, varscan2
- LDLRAD3 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 233/485 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs897155198, COSV100214821; called by muse, mutect2, varscan2
- MAGEC2 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 26/353 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.196); catalogued as rs142943547, COSV55997506, COSV55999092; called by muse, mutect2
- MBD3L3 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 261/825 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs1196514778; called by muse, mutect2, varscan2
- MEPE | c.806G>T p.G269V | Missense Mutation (SNP) | VAF 111/211 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63071884; called by muse, mutect2, varscan2
- MIS18A | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 122/304 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs761083966; called by muse, mutect2, varscan2
- MTMR10 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 144/359 reads (40%) | catalogued as rs753837494; called by muse, mutect2, varscan2
- MUC12 | c.13460C>T p.T4487I (on ENST00000379442; = p.T4344I on NM_001164462.1) | Missense Mutation (SNP) | VAF 174/2096 reads (8%) | SIFT tolerated, low confidence (0.08); catalogued as rs1315652498; called by muse, mutect2
- MXRA5 | c.2371C>T p.R791C | Missense Mutation (SNP) | VAF 292/292 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756893962, COSV54242793; called by muse, mutect2, varscan2
- NAV2 | c.5092C>T p.R1698W (on ENST00000396087 / NM_001244963.2; = p.R1642W on NM_145117.5) | Missense Mutation (SNP) | VAF 170/362 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs773808689; called by muse, mutect2
- NCOA4 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 189/385 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as rs782570752; called by muse, mutect2, varscan2
- NKX2-1 | c.392del p.P131Rfs*5 | Frame Shift Del (DEL) | VAF 194/510 reads (38%) | catalogued as COSV61389589; called by pindel, varscan2
- PDE3A | c.1742C>A p.P581Q | Missense Mutation (SNP) | VAF 110/250 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV100762798; called by muse, mutect2, varscan2
- SBNO2 | c.1425G>A p.M475I | Missense Mutation (SNP) | VAF 261/522 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs762056811; called by muse, mutect2, varscan2
- SPARCL1 | c.1679T>G p.I560S | Missense Mutation (SNP) | VAF 115/246 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56805012; called by muse, mutect2, varscan2
- TOPAZ1 | c.1571A>G p.E524G | Missense Mutation (SNP) | VAF 155/318 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1174282389; called by muse, mutect2, varscan2
- A2ML1 | c.542T>C p.V181A | Missense Mutation (SNP) | VAF 170/333 reads (51%) | SIFT tolerated (0.83); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ANKRD30A | c.2801A>T p.Q934L (on ENST00000611781; = p.Q878L on NM_052997.2) | Missense Mutation (SNP) | VAF 65/103 reads (63%) | SIFT tolerated (0.22); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ATP5F1A | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 170/335 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- BIRC6 | c.6365_6372del p.S2122Wfs*6 | Frame Shift Del (DEL) | VAF 35/119 reads (29%) | called by pindel, varscan2
- BIRC6 | c.6376C>T p.Q2126* | Nonsense Mutation (SNP) | VAF 41/132 reads (31%) | called by muse, varscan2
- DCDC2C | c.844A>G p.R282G | Missense Mutation (SNP) | VAF 97/221 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCLRE1A | c.1700C>G p.P567R | Missense Mutation (SNP) | VAF 216/442 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DMAC2L | c.76T>G p.F26V | Missense Mutation (SNP) | VAF 106/267 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- ELL2 | c.1349C>G p.P450R | Missense Mutation (SNP) | VAF 181/375 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- FLI1 | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 235/485 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FLNC | c.3035C>A p.P1012H | Missense Mutation (SNP) | VAF 318/665 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- MUC12 | c.10211C>T p.T3404I (on ENST00000379442; = p.T3261I on NM_001164462.1) | Missense Mutation (SNP) | VAF 106/2583 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2
- NKX2-1 | c.442dup p.D148Gfs*261 | Frame Shift Ins (INS) | VAF 218/657 reads (33%) | called by pindel, varscan2
- OR2J1 | c.638T>C p.I213T | Missense Mutation (SNP) | VAF 274/561 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- OR4E2 | c.363T>A p.D121E | Missense Mutation (SNP) | VAF 252/494 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDIA6 | c.624dup p.E209Rfs*27 | Frame Shift Ins (INS) | VAF 34/402 reads (8%) | called by mutect2, pindel
- PPP1R18 | c.611T>G p.L204R | Missense Mutation (SNP) | VAF 319/613 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- PROSER2 | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 315/562 reads (56%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- PTPN3 | c.1451dup p.T485Dfs*15 | Frame Shift Ins (INS) | VAF 154/396 reads (39%) | called by mutect2, pindel, varscan2
- RAB40A | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 304/322 reads (94%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SIGMAR1 | c.586T>G p.F196V | Missense Mutation (SNP) | VAF 351/351 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TMEM26 | c.386C>G p.A129G | Missense Mutation (SNP) | VAF 87/171 reads (51%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- UBASH3A | c.746T>A p.L249Q | Missense Mutation (SNP) | VAF 201/421 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR74 | c.262G>A p.G88S | Missense Mutation (SNP) | VAF 112/249 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ZC3H12B | c.2206A>G p.T736A | Missense Mutation (SNP) | VAF 261/281 reads (93%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZC3H7B | c.2806G>A p.D936N | Missense Mutation (SNP) | VAF 252/514 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARAP2 | c.4857G>A p.K1619= | Silent (SNP) | VAF 222/442 reads (50%) | catalogued as COSV58284361; called by muse, mutect2, varscan2
- BAIAP2L2 | c.585C>T p.S195= | Silent (SNP) | VAF 132/271 reads (49%) | catalogued as rs750948908; called by muse, mutect2, varscan2
- CDC42EP3 | c.552C>T p.G184= | Silent (SNP) | VAF 223/456 reads (49%) | called by muse, mutect2, varscan2
- CHD8 | c.1293A>G p.S431= (on ENST00000646647 / NM_001170629.2; = p.S152= on NM_020920.4) | Silent (SNP) | VAF 158/391 reads (40%) | called by muse, mutect2, varscan2
- DYRK2 | c.1380T>G p.G460= (on ENST00000344096 / NM_006482.3; = p.G387= on NM_003583.4) | Silent (SNP) | VAF 194/376 reads (52%) | called by muse, mutect2, varscan2
- FLNC | c.3036C>A p.P1012= | Silent (SNP) | VAF 322/676 reads (48%) | catalogued as COSV57964752; called by muse, mutect2, varscan2
- FTMT | c.102G>T p.P34= | Silent (SNP) | VAF 259/513 reads (50%) | catalogued as rs1428528606, COSV100360441; called by muse, mutect2, varscan2
- GPM6A | c.771G>A p.K257= | Silent (SNP) | VAF 215/395 reads (54%) | called by muse, mutect2, varscan2
- H1-6 | c.69G>A p.K23= | Silent (SNP) | VAF 43/386 reads (11%) | catalogued as rs369545877; called by muse, mutect2
- IGLV3-9 | c.297G>A p.G99= | Silent (SNP) | VAF 72/254 reads (28%) | called by muse, mutect2, varscan2
- KRTCAP3 | c.462T>C p.F154= | Silent (SNP) | VAF 15/307 reads (5%) | called by muse, mutect2
- MUC16 | c.6315T>C p.N2105= | Silent (SNP) | VAF 227/433 reads (52%) | called by muse, mutect2, varscan2
- MYO16 | c.4737G>A p.P1579= | Silent (SNP) | VAF 198/338 reads (59%) | called by muse, mutect2, varscan2
- NLRC3 | c.1395G>A p.A465= | Silent (SNP) | VAF 221/440 reads (50%) | catalogued as rs757640000, COSV57095457; called by muse, mutect2, varscan2
- OPRM1 | c.702G>T p.L234= | Silent (SNP) | VAF 206/438 reads (47%) | called by muse, mutect2, varscan2
- PCDHA7 | c.1170G>A p.T390= | Silent (SNP) | VAF 166/332 reads (50%) | catalogued as COSV65346327; called by muse, varscan2
- RADIL | c.3039C>T p.P1013= | Silent (SNP) | VAF 462/687 reads (67%) | catalogued as rs555843045; called by muse, mutect2, varscan2
- SLC34A1 | c.12C>T p.Y4= | Silent (SNP) | VAF 190/381 reads (50%) | catalogued as rs747607849; called by muse, mutect2, varscan2
- SLC6A3 | c.1266C>T p.S422= | Silent (SNP) | VAF 204/419 reads (49%) | catalogued as rs1246818027, COSV54364542, COSV54366912; called by muse, mutect2, varscan2
- SRSF8 | c.795G>A p.S265= | Silent (SNP) | VAF 133/299 reads (44%) | called by muse, mutect2, varscan2
- TEKT3 | c.804C>T p.D268= | Silent (SNP) | VAF 235/519 reads (45%) | catalogued as rs149266687; called by muse, mutect2, varscan2
- TENM3 | c.7872G>A p.A2624= | Silent (SNP) | VAF 239/404 reads (59%) | catalogued as rs367925910; called by muse, mutect2, varscan2
- TULP4 | c.1596A>G p.K532= | Silent (SNP) | VAF 153/337 reads (45%) | called by muse, mutect2, varscan2
- NPAP1L | n.29C>T | RNA (SNP) | VAF 125/254 reads (49%) | catalogued as rs1488657661; called by muse, mutect2, varscan2
- RIMBP2 | c.2362-1604C>T | Intron (SNP) | VAF 10/300 reads (3%) | called by muse, mutect2
- RTN1 | c.1766-23024_1766-23014del | Intron (DEL) | VAF 65/253 reads (26%) | called by mutect2, pindel, varscan2
- TNRC18 | c.487+118_487+126del | Intron (DEL) | VAF 69/296 reads (23%) | catalogued as rs11295332; called by mutect2, pindel*
- WDR26 | c.*128T>C | 3'UTR (SNP) | VAF 175/389 reads (45%) | called by muse, mutect2, varscan2
